Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAIG, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAIG-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Left orchidectomy; seminoma; diameter 5.0 cm; no angio-invasion present; no invasion in rete testis; invasion of tunica albuginea present; microlithiasis present; epididymis free of tumor; surgical margin of spermatic cord free of tumor.

Date of procurement (= date of orchidectomy):

ICD O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
JW 3/7/14

pathologist

professor of pathology

Source: NCI Genomic Data Commons file fba73a5a-1f9a-4904-8557-c084bc0615ec (TCGA-2G-AAIG-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).